Somatic mutation profile of tumor specimen 0E0848 from CCDI case PBCUZR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0848: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0063a6e-8737-405a-9e28-0a3ad3e4dd81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E084G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84aab573-4ba8-4369-ad3d-543eae8ac582

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRRC32 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 253/706 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs772672659, COSV52632332; called by muse, mutect2, varscan2
- NF1 | c.5273G>T p.G1758V (on ENST00000358273 / NM_001042492.3; = p.G1737V on NM_000267.3) | Missense Mutation (SNP) | VAF 17/539 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62228087; called by muse, mutect2
- NPHP4 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 325/929 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202179978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
